Somatic mutation profile of tumor specimen TCGA-B5-A5OD-01A (aliquot TCGA-B5-A5OD-01A-11D-A31U-09) from TCGA case TCGA-B5-A5OD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.8 years (24,775 days).
Specimen TCGA-B5-A5OD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bf76491-d837-4912-9a23-4912883d3cb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A5OD-10A (Blood Derived Normal), aliquot TCGA-B5-A5OD-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42806496-4cbd-44b8-9ac0-99264118cb4f

The open-access MAF lists 55 somatic variants for this specimen: 45 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 8, Frame Shift Del 3, Splice Region 2, Nonsense Mutation 2, 5'Flank 1, Frame Shift Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.6595del p.Y2199Ifs*65 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs398123753, CD105469, COSV56412672; ClinVar: pathogenic; called by mutect2, pindel
- SPOP | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61652945; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 14/14 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACE2 | c.1443G>A p.K481= | Splice Region (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99383125; called by muse, mutect2, varscan2
- ADARB2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67235567; called by muse, mutect2
- ADGRG2 | c.1226T>A p.L409H (on ENST00000379869 / NM_001079858.3; = p.L406H on NM_005756.4) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100492716; called by muse, mutect2, varscan2
- ALDH16A1 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV53197342, COSV99513237; called by muse, mutect2, varscan2
- ALDH16A1 | c.2245C>T p.Q749* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV99513238; called by muse, mutect2
- ARHGAP10 | c.476A>T p.H159L | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV100331768; called by muse, mutect2, varscan2
- CEP72 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.398); catalogued as COSV99375320; called by muse, mutect2, varscan2
- CSMD3 | c.10717G>A p.E3573K (on ENST00000297405 / NM_001363185.1; = p.E3404K on NM_052900.3) | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV99848226; called by muse, mutect2, varscan2
- CYFIP2 | c.649C>T p.H217Y | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV100557798; called by muse, mutect2, varscan2
- DNAJC5B | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV52535695, COSV99395865; called by muse, mutect2, varscan2
- DSCAM | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV101261569; called by muse, mutect2, varscan2
- ESYT1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745557343, COSV99920329; called by muse, mutect2, varscan2
- FAM78A | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100953468; called by muse, mutect2, varscan2
- FFAR1 | c.235T>C p.C79R | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99323788; called by muse, mutect2, varscan2
- FKBP10 | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV99505349; called by muse, mutect2, varscan2
- GHRHR | c.1210A>C p.T404P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.261); catalogued as COSV100396784; called by mutect2, varscan2
- GPR156 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1358985697, COSV59938545; called by muse, mutect2, varscan2
- GUSB | c.1879T>C p.W627R | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV100512776; called by muse, mutect2, varscan2
- HAS1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs773850679, COSV55786738; called by muse, mutect2, varscan2
- HYPK | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781154272, COSV99980139; called by muse, mutect2, varscan2
- KCNT2 | c.2103G>C p.K701N | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1363491636, COSV99656821; called by muse, mutect2, varscan2
- LAMA2 | c.1466A>G p.K489R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV101370844; called by muse, mutect2, varscan2
- MAGI3 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100290469; called by muse, mutect2, varscan2
- METTL18 | c.663G>A p.M221I | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99610203; called by muse, mutect2, varscan2
- MYH1 | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as rs762918988, COSV56848538; called by muse, mutect2, varscan2
- NBAS | c.5319T>A p.D1773E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs376517208; called by muse, mutect2, varscan2
- PCDHB11 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53382090, COSV99505048; called by muse, mutect2, varscan2
- PEX1 | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs150793635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGLS | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1479226836, COSV99395784; called by muse, mutect2, varscan2
- PLEKHH2 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV56758105, COSV99175110; called by muse, mutect2, varscan2
- PPP2R5A | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765582793, COSV99806968; called by muse, mutect2, varscan2
- PSME4 | c.1172A>T p.Q391L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV101122663; called by muse, mutect2, varscan2
- RBM6 | c.3021A>T p.G1007= | Splice Region (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99805937; called by muse, mutect2, varscan2
- SLC5A2 | c.1214T>C p.F405S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100393429; called by muse, varscan2
- SMC1A | c.3101T>C p.V1034A | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.34); catalogued as COSV100447689; called by muse, mutect2, varscan2
- SYNCRIP | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV100784333; called by muse, mutect2, varscan2
- TDRD1 | c.2798C>T p.T933M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs755901940, COSV99315181; called by muse, mutect2, varscan2
- TMEM145 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100004141; called by muse, mutect2, varscan2
- ARHGAP22 | c.679_682dup p.A228Gfs*45 | Frame Shift Ins (INS) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- ARHGAP35 | c.3995del p.L1332Rfs*30 | Frame Shift Del (DEL) | VAF 43/66 reads (65%) | called by mutect2, pindel, varscan2
- SLC25A10 | c.706-2_708del p.X236_splice | Splice Site (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- SLC5A1 | c.864_867del p.L288Ffs*22 | Frame Shift Del (DEL) | VAF 23/38 reads (61%) | called by mutect2, pindel, varscan2
- CBX4 | c.330C>T p.G110= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs759665188, COSV99490582; called by muse, mutect2, varscan2
- DUXA | c.297A>G p.R99= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV101617161; called by muse, mutect2
- EXOC7 | c.2181C>T p.I727= (on ENST00000335146 / NM_001145297.4; = p.I645= on NM_015219.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100135862, COSV58037086; called by muse, mutect2, varscan2
- ITGAL | c.999C>T p.V333= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- MAPK10 | c.1146G>A p.V382= (on ENST00000359221 / NM_001351625.2; = p.V420= on NM_002753.5) | Silent (SNP) | VAF 46/89 reads (52%) | catalogued as COSV100175473; called by muse, mutect2, varscan2
- PAPOLA | c.1554C>T p.L518= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV99354695; called by muse, mutect2, varscan2
- PLXNB2 | c.3549G>T p.V1183= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100834327; called by muse, mutect2, varscan2
- SEMA3D | c.1287G>A p.K429= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs1242700777, COSV99407456; called by muse, mutect2, varscan2
- MIRLET7B | n.70T>C | RNA (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- SUCO | chr1:172532484 C>A | 5'Flank (SNP) | VAF 10/40 reads (25%) | catalogued as rs1009606390, COSV99743854; called by muse, mutect2, varscan2
